Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4337, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4337-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Patient with left renal mass. Status-post left nephrectomy today. Now right renal re-vascularization.

Specimens Submitted:

- 1: SP: Left kidney, adrenal gland, perinephric fat and renal vein thrombus
- 2: SP: Para-aortic lymph node
- 3: SP: Right renal artery thrombus
- 4: SP: Right renal artery intima
- 5: SP: Spleen

DIAGNOSIS:

- 1) KIDNEY, LEFT, ADRENAL GLAND AND PERINEPHRIC ADIPOSE TISSUE; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL TYPE, NUCLEAR GRADE IV/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 6.8 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- INVASION OF THE RENAL VEIN IS PRESENT.
- WE ALSO NOTE TUMOR EMBOLI IN SMALL VESSELS.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS UNREMARKABLE.
- NO RENAL HILAR LYMPH NODES IDENTIFIED.
- 2) LYMPH NODE, PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE.
- 3) RENAL ARTERY THROMBUS, RIGHT; BIOPSY:
- FRESH BLOOD, FIBRIN AND LEUKOCYTES.
- NO TUMOR SEEN.
- 4) RENAL ARTERY INTIMA, RIGHT; BIOPSY:
- BENIGN VASCULAR WALL.
- NO TUMOR SEEN.
- 5) SPLEEN; SPLENECTOMY:
- BENIGN SPLEEN.
- THREE BENIGN LYMPH NODES (0/3).
- NO TUMOR SEEN.
-

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Special Studies:

Result

Special Stain
RECUT

Comment

Gross Description:

1) The specimen is received fresh, labeled, "Left kidney, adrenal gland, perinephric fat and renal vein thrombus". It consists of a radical nephrectomy specimen composed of a kidney, adrenal gland and perinephric adipose tissue, weighing 330 grams and measuring 13.2 x 9.8 x 3.4 cm. The external surface is inked black. The upper half of the kidney is replaced by an ill-defined, vaguely, lobulated, variegated tumor mass, measuring 6.8 x 5.7 x 3.2 cm, located 1.1 cm from the adrenal gland. The tumor extends into the renal vein from which the tumor grows distally as an exophytic polypoid mass, measuring 3.6 cm in length. The tumor also extends into the pelvis. However, grossly ureter margin and vascular margins are free of tumor. The tumor appears to extend to, but not through, the overlying renal capsule. On cut sections, the tumor is yellow-tan, friable tissue with multiple cystic degeneration and necrosis. The remaining kidney appears to be unremarkable. The adrenal gland measures 4.2 x 2.0 x 0.7 cm, and is unremarkable. No lymph nodes are identified in the perinephric adipose tissue, therefore, representative sections are submitted for histology. Photographs are taken. Small samples are given to TPS.

Summary of Sections:

M – margin (1-M1 contains the margin of the renal vein that contains the tumor)

T – tumor (1-T3 contains the tumor in the renal vein)

LT – random sections of the non-tumor kidney

FAT – perinephric adipose tissue

2) The specimen is received in formalin, labeled, "Para-aortic lymph node". It consists of a lymph node, measuring 1.9 x 0.5 x 0.3 cm. Entirely submitted.

Summary of Sections:

LN – lymph node

3) The specimen is received in formalin, labeled, "Right renal artery thrombus". It consists of multiple fragments of blood clot, measuring up to 0.6 cm in greatest dimension in aggregate. Entirely submitted.

Summary of Sections:

U – undesignated

4) The specimen is received in formalin, labeled, "Right renal artery intima". It consists of a single minute piece of pink-tan soft tissue, measuring 0.1 cm in greatest dimension. Entirely submitted and is dabbled in Mercurochrome.

Summary of Sections:

U – undesignated

5) The specimen is received fresh, labeled, "Spleen". It consists of a spleen measuring 12.5 x 7.5 x 2.2 cm and weighing 220 grams. The splenic capsule is purple gray, intact and glistening. Attached to the hilum of the spleen is the fatty tissue, marked by a clip, where embedded are probable splenic nodes measuring up to 0.2 cm in greatest dimension. The spleen is serially sectioned revealing hemorrhagic, glistening slightly granular cut surface without any discrete mass. Random sections of the specimen are submitted.

Summary of Sections:

VM – vascular margin

PHM – probable hilar nodes

U – undesignated random section of the capsule with the splenic parenchyma

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: SP: Left kidney, adrenal gland, perinephric fat and renal vein thrombus

Block	Sect. Site	PCs
1	FAT	2
2	LK	2
2	M	5
11	T	13

Part 2: SP: Para-aortic lymph node

Block	Sect. Site	PCs
1	ln	1

Part 3: SP: Right renal artery thrombus

Block	Sect. Site	PCs
1	u	10

Part 4: SP: Right renal artery intima

Block	Sect. Site	PCs
1	U	1

Part 5: SP: Spleen

Block	Sect. Site	PCs
2	PLN	2
5	U	5
1	VM	10

Source: NCI Genomic Data Commons file a6138567-a851-464f-8fab-2a0e8f0456ac (TCGA-BP-4337.B0B3C3BF-A828-4F06-AC69-C2E664D1A2F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).